Somatic mutation profile of tumor specimen TCGA-05-4434-01A (aliquot TCGA-05-4434-01A-01D-1265-08) from TCGA case TCGA-05-4434, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-05-4434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 467027c9-4691-4da8-aca0-55410f41c4e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4434-10A (Blood Derived Normal), aliquot TCGA-05-4434-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9510a555-586e-470f-855d-79a7e687cc44

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 27, Silent 14, Frame Shift Del 4, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3B | c.134A>C p.D45A | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.035); catalogued as COSV55446048; called by muse, mutect2, varscan2
- ALDH1A3 | c.493T>A p.F165I | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV60900731; called by muse, mutect2, varscan2
- CD4 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.69); catalogued as COSV50589019; called by muse, mutect2, varscan2
- ERBB2 | c.2326_2327insTAT p.G776delinsVC | In Frame Ins (INS) | VAF 20/88 reads (23%) | catalogued as COSV54064203, COSV54064477, COSV54066307, COSV54066802, COSV54077015, COSV99507093; called by mutect2, pindel, varscan2
- ERBB3 | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57246339; called by muse, mutect2, varscan2
- FBXO43 | c.2035G>C p.E679Q | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV101413827, COSV71054426; called by muse, mutect2, varscan2
- FBXO43 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV101413828; called by muse, mutect2
- FOXF2 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1383690197, COSV52524940; called by muse, mutect2
- IFNLR1 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59525104; called by muse, mutect2
- LAMA1 | c.5916G>C p.L1972F | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV67531639; called by muse, mutect2
- LRRTM4 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs756905050, COSV69138884; called by muse, mutect2, varscan2
- MYH1 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 27/225 reads (12%) | catalogued as COSV56843288; called by muse, mutect2, varscan2
- MYH9 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53381732; called by muse, mutect2, varscan2
- NEPRO | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58722531; called by muse, mutect2, varscan2
- NFAT5 | c.1748A>G p.D583G | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63024960; called by muse, mutect2, varscan2
- NLRP5 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV66761866; called by muse, varscan2
- NLRP5 | c.3593G>A p.W1198* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV66761871; called by muse, varscan2
- NVL | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55869935; called by muse, mutect2
- PARP14 | c.1382A>G p.K461R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV71734073; called by muse, mutect2
- PARP9 | c.222A>T p.L74F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1456226315, COSV64449815; called by muse, mutect2
- PCDH9 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 10/324 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60526466; called by muse, mutect2
- PCDHGA6 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV53894971; called by muse, mutect2
- PMFBP1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 61/593 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV52820376; called by muse, mutect2, varscan2
- RPAIN | c.194T>A p.M65K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99851557; called by muse, mutect2
- SLC22A3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs183669984, COSV51709910; called by muse, mutect2
- SLC2A8 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs374408636; called by muse, mutect2, varscan2
- SLC5A1 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV56683180; called by muse, mutect2, varscan2
- SNX30 | c.395G>T p.R132I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65292025; called by muse, mutect2, varscan2
- STAC3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60413303; called by muse, mutect2, varscan2
- STX8 | c.118-2A>T p.X40_splice | Splice Site (SNP) | VAF 23/93 reads (25%) | catalogued as COSV60487590; called by muse, mutect2, varscan2
- UNC13A | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs939817904, COSV53187683; called by muse, mutect2, varscan2
- KDM5C | c.3059del p.Q1020Rfs*35 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- KMT2C | c.4192_4193del p.N1398Hfs*15 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- NCOA2 | c.162del p.F54Lfs*7 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- PPP1CA | c.535del p.D179Tfs*73 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel
- PRRC2A | c.6442dup p.D2148Gfs*25 | Frame Shift Ins (INS) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1569G>A p.L523= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs1447099338, COSV62321144; called by muse, mutect2, varscan2
- ASCC2 | c.1626T>C p.N542= | Silent (SNP) | VAF 33/197 reads (17%) | catalogued as rs752143875, COSV57071777; called by muse, mutect2, varscan2
- BEND3 | c.1767G>A p.E589= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1554231454, COSV100944568; called by muse, mutect2, varscan2
- CCDC116 | c.162C>T p.S54= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV53037093; called by muse, mutect2, varscan2
- CD72 | c.435C>G p.L145= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV52410084; called by muse, mutect2
- CHN1 | c.327C>T p.R109= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV69294692; called by muse, mutect2
- FGF16 | c.531T>C p.T177= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV101466311; called by muse, mutect2, varscan2
- IMPG1 | c.678A>T p.T226= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV64054025; called by muse, mutect2, varscan2
- LASP1 | c.114A>G p.T38= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV58802437; called by muse, mutect2, varscan2
- OXTR | c.318C>T p.Y106= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV57478306, COSV57478956; called by muse, mutect2
- SEMA3D | c.1596C>T p.H532= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV52386890; called by muse, mutect2, varscan2
- SYNE1 | c.4620A>G p.A1540= (on ENST00000367255 / NM_182961.4; = p.A1547= on NM_033071.3) | Silent (SNP) | VAF 16/472 reads (3%) | catalogued as COSV54900661; called by muse, mutect2
- TEX2 | c.3036G>A p.K1012= (on ENST00000583097 / NM_001288733.2; = p.K1019= on NM_018469.5) | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs749037215, COSV51977206; called by muse, mutect2, varscan2
- ZNF770 | c.1149A>G p.R383= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs531029586, COSV62543827; called by muse, mutect2
